Somatic mutation profile of tumor specimen ALCH-B4SE-TTP1-A (aliquot ALCH-B4SE-TTP1-A-5-0-D-A81V-36) from ALCHEMIST case ALCH-B4SE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.8 years (30,249 days).
Specimen ALCH-B4SE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f1fadab-5d1f-483a-a51a-f44bb38d6d95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4SE-NB1-A (Blood Derived Normal), aliquot ALCH-B4SE-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1404aa34-3085-46c8-8ec5-0299f2e6dbd2

The open-access MAF lists 61 somatic variants for this specimen: 43 protein-altering or splice-affecting, 6 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Intron 7, Silent 6, RNA 3, Nonsense Mutation 2, In Frame Del 1, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 142/743 reads (19%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- PTEN | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 109/920 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554898129, CM110132, COSV64288974, COSV64292774, COSV64296979; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.10278A>C p.E3426D | Missense Mutation (SNP) | VAF 152/633 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs746917275; called by muse, mutect2, varscan2
- ALPK2 | c.5744G>A p.R1915H | Missense Mutation (SNP) | VAF 35/304 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs140586410; called by muse, mutect2, varscan2
- GPR108 | c.1264C>T p.R422W (on ENST00000264080 / NM_001080452.1; = p.R180W on NM_020171.2) | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1185608168; called by muse, mutect2
- LETM1 | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.196); catalogued as rs762737209, COSV100245164, COSV57100334; called by muse, mutect2, varscan2
- MYH2 | c.5579C>T p.T1860M | Missense Mutation (SNP) | VAF 61/548 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs148724880; called by muse, mutect2, varscan2
- NUDT15 | c.97A>G p.K33E | Missense Mutation (SNP) | VAF 46/533 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs768057637; called by muse, mutect2
- PHACTR3 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 268/519 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.186); catalogued as COSV63027663; called by muse, varscan2
- PLEKHH1 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 28/540 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.633); catalogued as rs188512358; called by muse, mutect2
- POM121L12 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1021830435, COSV68692627; called by muse, mutect2, varscan2
- PTPRG | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 43/369 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs755528856; called by muse, mutect2, varscan2
- RBM19 | c.266G>A p.W89* | Nonsense Mutation (SNP) | VAF 46/374 reads (12%) | catalogued as rs367915316; called by muse, mutect2, varscan2
- RFLNA | c.488G>A p.R163H (on ENST00000546355 / NM_001365156.1; = p.R82H on NM_181709.4) | Missense Mutation (SNP) | VAF 77/480 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs767385958, COSV58038086; called by muse, mutect2, varscan2
- TNFRSF25 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 34/395 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs1455854052; called by muse, mutect2
- DGKD | c.1748T>C p.I583T (on ENST00000264057 / NM_152879.3; = p.I539T on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/541 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.012); called by muse, mutect2
- GAPDHS | c.741+3G>A | Splice Region (SNP) | VAF 82/273 reads (30%) | called by muse, mutect2, varscan2
- GPR15 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- HAUS4 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HPN | c.948A>G p.I316M | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSPA6 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 130/1474 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANK2 | c.1388C>T p.S463F | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- KERA | c.557A>G p.D186G | Missense Mutation (SNP) | VAF 26/599 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.224); called by muse, mutect2
- MTDH | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.927); called by muse, mutect2
- MTREX | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 41/413 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHACTR3 | c.1641T>A p.H547Q | Missense Mutation (SNP) | VAF 266/518 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- PLCB3 | c.1300G>A p.G434R | Missense Mutation (SNP) | VAF 15/448 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLPBP | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2
- POGLUT3 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- PRDM9 | c.2623C>G p.L875V | Missense Mutation (SNP) | VAF 74/544 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PTPN3 | c.262A>C p.S88R | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- RFX7 | c.1219G>A p.E407K (on ENST00000559447 / NM_001368074.1; = p.E504K on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- RHOC | c.137T>G p.I46S | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SASH1 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); called by muse, mutect2
- SDC1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 30/200 reads (15%) | called by muse, mutect2, varscan2
- SH2B3 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC13A5 | c.1634A>C p.N545T | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPINK9 | c.236A>T p.K79I | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2
- SPTA1 | c.788C>A p.A263D | Missense Mutation (SNP) | VAF 34/888 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- TNN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TRPS1 | c.166C>T p.H56Y (on ENST00000220888 / NM_001330599.2; = p.H69Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/1156 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- VPS13D | c.5387A>C p.H1796P | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.364); called by muse, mutect2
- ZNF592 | c.3101A>G p.N1034S | Missense Mutation (SNP) | VAF 125/992 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DENND1B | c.1948C>A p.R650= | Silent (SNP) | VAF 426/1365 reads (31%) | called by muse, mutect2, varscan2
- FAM166A | c.675T>C p.R225= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as rs1016253793; called by muse, mutect2, varscan2
- LRTOMT | c.444T>C p.Y148= | Silent (SNP) | VAF 42/250 reads (17%) | catalogued as rs968079096; called by muse, mutect2, varscan2
- NUDT15 | c.96G>A p.G32= | Silent (SNP) | VAF 45/536 reads (8%) | called by muse, mutect2
- RASSF2 | c.843G>A p.P281= | Silent (SNP) | VAF 30/592 reads (5%) | catalogued as rs746840494; called by muse, mutect2
- WDFY4 | c.7425C>T p.R2475= | Silent (SNP) | VAF 12/211 reads (6%) | called by muse, mutect2
- ADAM15 | c.80-116C>T | Intron (SNP) | VAF 37/288 reads (13%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840846 G>A | 5'Flank (SNP) | VAF 212/631 reads (34%) | called by muse, varscan2
- AL163540.1 | n.284T>A | RNA (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- AL772337.1 | n.858-10G>A | Intron (SNP) | VAF 4/50 reads (8%) | catalogued as rs1271583017; called by muse, mutect2
- BX119917.1 | n.229C>T | RNA (SNP) | VAF 22/215 reads (10%) | catalogued as rs747731775; called by muse, mutect2, varscan2
- C19orf12 | chr19:29700786 T>G | 3'Flank (SNP) | VAF 51/352 reads (14%) | called by muse, mutect2, varscan2
- FAM169B | n.755G>C | RNA (SNP) | VAF 46/410 reads (11%) | called by muse, mutect2, varscan2
- NLE1 | c.1214+194G>A | Intron (SNP) | VAF 20/162 reads (12%) | called by muse, varscan2
- RBM39 | c.52-70C>T | Intron (SNP) | VAF 216/860 reads (25%) | called by muse, varscan2
- SAT1 | c.119-40T>A | Intron (SNP) | VAF 83/785 reads (11%) | called by muse, mutect2, varscan2
- TRAPPC6A | c.84+39C>T | Intron (SNP) | VAF 19/135 reads (14%) | called by muse, mutect2, varscan2
- TTC38 | c.616-1415C>T | Intron (SNP) | VAF 70/337 reads (21%) | catalogued as COSV66845328; called by muse, mutect2, varscan2
